Surgical pathology report (de-identified scan), TCGA case TCGA-08-0347, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0347-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

TCGA-08-347

FINAL PATHOLOGIC DIAGNOSIS

- A. RIGHT TEMPORAL LOBE, BIOPSY: GLIOBLASTOMA, SEE COMMENT.
- B. RIGHT TEMPORAL LOBE, BIOPSY: GLIOBLASTOMA, SEE COMMENT.

COMMENT:

NOTES:

COMMENT: Necrosis, mitoses, endothelial proliferation, and nuclear and cytoplasmic pleomorphism are prominent, making this a grade IV glioblastoma by the [REDACTED] criteria and a glioblastoma multiforme using the [REDACTED] criteria.

Microscopic Description

Diagnosis based on gross and microscopic examinations.

Gross Description

The specimen is received in two parts.

Part A is received fresh from the OR, labeled with the patient's name and number only, and consists of two pieces of tan-red tissue measuring 1.6 x 0.6 x 0.3 cm in aggregate. A portion is submitted for frozen section #1 and then permanently embedded in cassette A1. The remaining, unfrozen tissue is submitted in entirety in cassette A2.

FROZEN SECTION DIAGNOSIS

Highly anaplastic astrocytoma--no necrosis seen. (No record of previous surgery). ([REDACTED])

Part B received in formalin in a container labeled with patient's name and number only consists of a

[page 2 of 2]
tan-white and red soft tiss. fragment measuring approximately 3 x 2.0 x 0.7 cm in greatest dimension. Representative samples are submitted in cassettes B1, B2 and B3.

Clinical History

with right temporal glioblastoma.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically Signed Out By Conversion

Source: NCI Genomic Data Commons file 7c5e1504-383b-4a24-9f0c-49a12e978ffc (TCGA-08-0347.36221D91-07FA-4620-9944-1FA8BEA9DAA5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).